CCDI case PBCPMY — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Prostate gland.
https://portal.gdc.cancer.gov/cases/9757129c-1b97-4ddf-98e7-53db990cc75d

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8900/3; Tissue or organ of origin: Prostate gland; Age at diagnosis: 17.3 years (6,321 days).

Biospecimens (3 samples)
- Sample 0DWWMD: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Samples 0DWWML, 0DWWN4 (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue.
